ALCHEMIST case ALCH-B3CJ — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/a8091955-c311-4944-8607-ba4b580fd28b

Demographics
Sex at birth: female.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: Age at diagnosis: 77.0 years (28,123 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B3CJ-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B3CJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B3CJ-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 90; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 100; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 50.
